Surgical pathology report (de-identified scan), TCGA case TCGA-97-A4M3, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-A4M3-01A (Primary Tumor).

[page 1 of 11]
ICD-0-3

adenocarcinoma, of mixed subtypes 8255/3

Site: lung, ^(c) upper lobe c34.1

SURGICAL PATHOLOGY REPORT

COLLECTION DATE:

hw
10/4/12

SPECIMENS:

1. F/S APICAL BIOPSY
2. F/S APICAL SEGMENT OF RIGHT UPPER LOBE
3. 5TH RIB, RIGHT
4. RIGHT LEVEL 10 LYMPH NODE
5. RIGHT LEVEL 4 LYMPH NODE
6. RIGHT LEVEL 7 LYMPH NODE
- SEE ADDENDUM

Reason For Addendum #1: Molecular Studies

Reason For Addendum #2: Molecular Studies

Reason For Addendum #3: Molecular Studies

Reason For Addendum #4: Biomarker Report

DIAGNOSIS:

1. LUNG, RIGHT UPPER LOBE, APEX: BIOPSY

- ADENOCARCINOMA WITH PAPILLARY AND MICROPAPILLARY PATTERNS.

2. LUNG, RIGHT UPPER LOBE, APICAL SEGMENT: SEGMENTECTOMY

- ADENOCARCINOMA, LEPIDIC PREDOMINANT (2.9 CM), SEE NOTE.
- THE BRONCHIAL AND VASCULAR MARGINS ARE FREE OF TUMOR.
- SUBPLEURAL FIBROELASTOTIC SCAR, CONSISTENT WITH APICAL CAP.

Note: The tumor consists of lepidic (40%), acinar (30%), papillary (20%) and micropapillary (10%) components and measures 2.9 cm in greatest dimension microscopically. Results of molecular studies will be reported in addenda.

3. RIB, RIGHT 5TH: EXCISION

- BONE AND BONE MARROW WITH TRILINEAGE HEMATOPOESIS.

[page 2 of 11]
4. LYMPH NODE, RIGHT LEVEL 10: BIOPSY
- THREE BENIGN LYMPH NODES (0/3).

5. LYMPH NODE, RIGHT LEVEL 4: BIOPSY
- FOUR BENIGN LYMPH NODES (0/4).

6. LYMPH NODE, RIGHT LEVEL 7: BIOPSY
- FIVE BENIGN LYMPH NODES (0/5).

Specimens: 1: F/S APICAL BIOPSY
2: F/S APICAL SEGMENT OF RIGHT UPPER LOBE
3: 5TH RIB, RIGHT
4: RIGHT LEVEL 10 LYMPH NODE
5: RIGHT LEVEL 4 LYMPH NODE
6: RIGHT LEVEL 7 LYMPH NODE

LUNG: Resection

SPECIMEN

Specimen: Lobe(s) of lung (specify)
right upper

Procedure: Segmentectomy

Specimen Laterality: Right

Tumor Site: Upper lobe

Tumor Focality: Unifocal

TUMOR

Histologic Type: Adenocarcinoma, mixed subtype

Histologic Grade: G1: Well differentiated

EXTENT

Tumor Size: Greatest dimension (cm)
2.9cm

Visceral Pleura Invasion: Not identified

MARGINS

Bronchial Margin

Bronchial Margin Involvement by Invasive Carcinoma: Uninvolved by
invasive carcinoma

Vascular Margin: Uninvolved by invasive carcinoma

ACCESSORY FINDINGS

Lymph-Vascular Invasion: Not identified

STAGE (pTNM)

Primary Tumor (pT):

pT1b: Tumor greater than 2 cm, but 3 cm or less in greatest
dimension, surrounded by lung or visceral pleura, without
bronchoscopic evidence of invasion more proximal than the lobar
bronchus (i.e., not in the main bronchus)

Regional Lymph Nodes (pN)

[page 3 of 11]
pN0: No regional lymph node metastasis
Distant Metastases (pM): Not applicable

Pathologist

CLINICAL HISTORY AND PRE - OPERATIVE DIAGNOSIS:

F ex-smoker (35-40 pack-years) with a LUL adenocarcinoma, a 2.3 cm RUL mixed solid and ground-glass nodule and multiple additional bilateral lung nodules.

MACROSCOPIC DESCRIPTION:

The specimen is received in six parts, each labeled with the patient's name.

1. Part one is received fresh, labeled 'apical biopsy'. It consists of one piece of tan-pink soft tissue measuring 0.7 x 0.4 x 0.3 cm. Entirely submitted in one cassette.
2. Part two is received in saline, labeled 'apical segment of right upper lobe (stitch on bronchial margin)'. It consists of a 48 grams segmentectomy specimen measuring 9 x 5.5 x 1.5 cm. The specimen has a stapled margin which spans the length of the specimen. The bronchial margin has a suture and it measures 0.5 cm in length. The specimen is serially sectioned to reveal a tan-yellow nodule measuring 1.2 x 1 x 0.4 cm. The pleural surface overlying the nodule is inked black. The stapled line is inked blue. The remaining lung parenchyma has a tan-red appearance. There is also a 0.4 cm firm area seen away from the main tumor. Representative sections submitted.
3. Part three is received in formalin, labeled '5th rib, right '. It consists of one segment of rib measuring 1.4 x 1.3 x 0.6 cm. A representative section is placed in decalcifying solution and then submitted.
4. Part four is received in saline, labeled 'right level 10 lymph node '. It consists of multiple pieces of tan soft tissue measuring 1.1 x 1 x 0.5 cm in aggregate. The specimen is submitted entirely.
5. Part five is received in saline, labeled 'right level 4 lymph node '. It consists of multiple pieces of yellow fatty tissue measuring 1.7 x 1.6 x 0.7 cm. Multiple possible lymph nodes are identified, largest of which measures 0.7 cm in greatest dimension. The specimen is submitted entirely.

[page 4 of 11]
6. Part six is received in saline, labeled 'right level 7 lymph node'. It consists of multiple pieces of tan soft tissue measuring 1.2 x 0.7 x 0.5 cm in aggregate. The specimen is submitted entirely.

SUMMARY OF SECTIONS:

1A entirely submitted
2A froze section control, bronchial margin
2B vascular margin
2C tumor to pleura
2D-2E sections of tumor
2F tumor to stapled blue margin
2G-2H lung parenchyma adjacent to tumor
2I firm area grossly away from tumor
3A representative
4A in toto
5A lymph node, bisected
5B remainder of specimen
6A in toto

SPECIAL PROCEDURES:

INTRA - OPERATIVE CONSULTATION:

1. Lung, right apex: biopsy (FS)
- Invasive adenocarcinoma.

2. Lung, right upper lobe, apical segment: segmentectomy (FS)
- No tumor is seen at the bronchial margin.

Intra-Operative Consultation #1 performed by

[page 5 of 11]
Final Diagnosis performed by

ADDENDUM #1 FOR MOLECULAR TESTS:

KRAS, EGFR and ALK FISH were sent on

The test is to be performed on

The case report, slides, and blocks for the cited accession number were retrieved from archives. The pathologist whose signature appears below reviewed the original pathology report, examined candidate H&E slides, and selected block 2C appropriate to the specifications of the ordered molecular analysis. x1 H&E and x9 unstained slides were prepared and forwarded to

where the subject molecular test will be performed. An addendum report will be issued when the results of this molecular test are available.

Addendum #1 performed by

ADDENDUM #2:

EGFR Mutation Analysis

Referring Physician:

Body Site: Right upper lobe of lung

Clinical Data: Adenocarcinoma

RESULTS: No mutation detected.

INTERPRETATION: No mutations were identified in the sample provided for analysis. Fewer than 5% of non-small cell lung carcinoma patients without identifiable mutations are reported to be responsive to EGFR tyrosine kinase inhibitor therapies.

COMMENT: Forty percent (40%) or more tumor cellularity is optimal for this mutation analysis. The sample submitted showed 90% tumor

[page 6 of 11]
cellularity upon pathologist review.

A frequently occurring sequence change 2361>GA (Q787Q) was identified. This polymorphism is known not to have clinical significance.

Mutations in the tyrosine kinase domain of the epidermal growth factor receptor (EGFR) gene are reported to be associated with differential responsiveness or resistance to EGFR tyrosine kinase inhibitor (TKI) therapies. The objective response rate among patients with a sensitizing mutation ranges from 55 to 82%.

This assay analyzes exons 18-21 of the EGFR tyrosine kinase domain; based on the current literature, most mutations in non-small-cell lung carcinoma (NSCLC) are expected to occur in these exons. Mutations present in less than 10-20% of extracted DNA may not be detected by this method. Mutation status in a sample may change during tumor progression or the course of therapy; therefore, this result cannot be used to infer the presence or absence of a mutation in another sample or sub-sample obtained from this tumor.

This test is validated for non-small cell lung carcinoma. The clinical significance and utility of this test in other tumor types is unknown.

METHOD:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exons 18-21 of the EGFR gene. PCR products are analyzed by bi-directional direct DNA sequencing using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

1. Azzoli CG, et al. J Clin Oncol. 20095; 27:6251-6266.
2. Jackman DM et al. Clin Carcinoma Res. 2009; 15:5267-5273
3. Mok TS, et al. N Engl J Med. 1009; 361:947-957
4. Sharma SV, et al. Nat Rev Carcinoma, 2007; 7:169-181.

DISCLAIMER:

This test was developed and its performance characteristics determined by _____ The laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical

[page 7 of 11]
testing. This particular test is not considered a stand alone test and should be used only in the context of other diagnostic tests or clinical work-up related to treatment decisions.

Addendum #2 performed by

ADDENDUM 3:

Integrated Oncology

MOLECULAR ONCOLOGY
KRAS MUTATION ANALYSIS

Clinical Data: Adenocarcinoma

RESULTS: Wild type gene.

INTERPRETATION: No mutations were identified at codons 12 and 13 of the KRAS gene.

COMMENT:

Mutations in the KRAS gene are reported to be associated with poor

[page 8 of 11]
prognosis, and resistance to targeted tyrosine kinase inhibitor therapies in patients with non-small-cell lung cancer (NSCLC). KRAS mutations occur in 15-30% of NSCLC patients and are strongly associated with adenocarcinoma and smoking history.

This assay analyzes codons 12 and 13 in exon 2 of the KRAS gene; based on the current literature, approximately 98% of mutations are expected to occur in these codons. The analytical sensitivity of the assay is approximately 10%; thus mutations present in a low percentage of cells may not be detected. This test is validated for use in identifying KRAS codon 12 and codon 13 mutations in fresh, frozen, or formalin-fixed paraffin embedded tissue. In particular the test performance has been established in samples of colorectal cancer and non-small cell lung carcinoma which harbor these mutations, although several other tissues are also known to harbor KRAS mutations (e.g. tumors of pancreas, bile duct, ovary, appendix, etc.).

Analysis of EGFR mutation or gene amplification status may provide additional information regarding this patient's probability of response to targeted tyrosine kinase inhibitor therapies, if clinically indicated. See references.

METHOD/LIMITATION:

Tissue sections are reviewed by a pathologist and relevant tumor is selected for analysis. DNA is isolated from the sample, quantified and amplified by polymerase chain reaction (PCR) using primers to exon 2 of the KRAS gene. PCR products are subjected to single nucleotide primer extension to detect mutations at codons 12 and 13; primer extension products are analyzed using capillary gel electrophoresis and fluorescence detection. False positive or negative results may occur for reasons that include genetic variants or somatic heterogeneity of the tissue sample.

REFERENCES:

NSCLC

Mascaux C, Iannino N, et al. British Journal of Cancer, 2005; 92:11-139

Pao W, Wang TY, et al. PLoS Medicine, 2005; 2(1):57-61

Eberhard DA, Johnson BE, et al. J Clin Oncol, 2005; 23:5900-5909

Han SW, Kim TY, et al. Clin Cancer Res. 2006; 12(8):2538-2544

CRC

DiFiore C, Blanchard F, et al. Br J Cancer, 20007; 96:1166-1169

Lievre A, Bachet J-B, et al. Cancer Res, 2006; 66:3992-3995,

This test was developed and its performance characteristics

[page 9 of 11]
determined by laboratory is regulated under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. This particular test is not considered a stand alone test and should be only used in the context of other diagnostic tests or clinical work-up related to treatment decisions.

Addendum #3 performed by

ADDENDUM 4:

Fluorescence In-Situ Hybridization (FISH)

Referring Physician

Body Site: Right upper lobe of lung

Clinical Data: Adenocarcinoma.

INTERPRETATION:

Negative for a rearrangement involving the ALK gene.

Probe #Nuclei Examined % Positive Nuclei %

Control values

2p23(ALK)V 50 0 <15.0

A total of 50 cells were scored.

FINDINGS: FISH was performed on paraffin embedded tissue sections using dual color break-apart probe (to the ALK

[page 10 of 11]
gene at 2p23. This probe flanks the entire gene. If a rearrangement involving ALK is present, inversion or translocation, one of the two probe signals separates as one red (orange) and one green signal. In this specimen, separated signals were present in 0.5% of the nuclei scored. Based on laboratory validation data, these results are within the normal limits.

COMMENTS: Three copies of ALK were observed in 32.0% of cells. This gain of intact ALK fusion hybridization signals represents an aneuploid population with extra copies of chromosomes 2/2p ALK region. Additional copies of ALK are not uncommon in NSCLCs, although the significance of extra copies of the ALK gene in lung carcinoma is unclear at this time (Salido M. et al. J Thorac Oncol. 2011;6:21-27)

ISCN RESULTS: nuc ish(ALKx3 4)[38/50]

—

This Vysis ALK Break Apart Probe FISH test () is FDA approved for use in the detection of rearrangements involving the ALK gene via fluorescence in situ hybridization (FISH) in formalin-fixed paraffin-embedded (FFPE) non-small cell lung cancer (NSCLC) tissue specimens.

Addendum #4 performed by

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by Department of Pathology.

[page 11 of 11]
They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Prior Malignancy History	Base Cell	✓

Source: NCI Genomic Data Commons file 2fb0405a-3809-4333-abeb-5767c57cb1da (TCGA-97-A4M3.49E1FE02-A4A8-4805-88B1-ADB915F879DF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).